Somatic mutation profile of tumor specimen 0DPAOE from CCDI case PBCDDC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.2 years (2,615 days).
Specimen 0DPAOE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0ca0364-7dae-471f-b2c3-6945db8a9b63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPAO8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ba02124-353a-4e01-b139-569c5a2c5819

The open-access MAF lists 49 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, RNA 2, Splice Site 1, Frame Shift Ins 1, 5'UTR 1, 3'UTR 1, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 531/1348 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL4 | c.3053G>A p.R1018H | Missense Mutation (SNP) | VAF 281/721 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs759216315; called by muse, mutect2, varscan2
- AEBP1 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 78/1816 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56260987; called by muse, mutect2
- ATP8B1 | c.3643C>T p.R1215W | Missense Mutation (SNP) | VAF 290/734 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201877094; called by muse, mutect2
- CD163 | c.2381G>A p.R794H | Missense Mutation (SNP) | VAF 846/1520 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762219071, COSV63132133, COSV63136988; called by muse, mutect2, varscan2
- CFP | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 262/314 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1454386310, COSV99057889; called by muse, mutect2, varscan2
- IFNA5 | c.506C>A p.A169E | Missense Mutation (SNP) | VAF 358/1117 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs557350282; called by muse, mutect2, varscan2
- KCNA4 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 260/596 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as rs373415782, COSV60252106; called by muse, mutect2, varscan2
- KMT2C | c.473G>C p.G158A | Missense Mutation (SNP) | VAF 570/2108 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV100067181; called by muse, mutect2, varscan2
- MANBA | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 247/628 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV56963323; called by muse, mutect2, varscan2
- MAP3K14 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 834/927 reads (90%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs369289282; called by muse, mutect2, varscan2
- PCNX2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 444/1129 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs776043496; called by muse, mutect2, varscan2
- PIEZO1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 333/863 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs953279288; called by muse, mutect2, varscan2
- RIOX2 | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 383/993 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs777509209; called by muse, mutect2, varscan2
- RP1L1 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 190/1208 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs201120801; called by muse, varscan2
- SORCS3 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 226/537 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746780027, COSV63815365; called by muse, mutect2, varscan2
- ZBTB40 | c.2734G>C p.V912L | Missense Mutation (SNP) | VAF 30/1014 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV65146231; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 52/1494 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DYNC1H1 | c.4448A>G p.K1483R | Missense Mutation (SNP) | VAF 785/1706 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- DYTN | c.258_265dup p.T89Rfs*5 | Frame Shift Ins (INS) | VAF 251/812 reads (31%) | called by mutect2, varscan2
- EMC7 | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 453/1088 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GLS2 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 311/1363 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- M1AP | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 27/812 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MED24 | c.2624C>T p.T875I | Missense Mutation (SNP) | VAF 145/356 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, varscan2
- PHF12 | c.2326C>T p.H776Y | Missense Mutation (SNP) | VAF 268/719 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- PLA1A | c.1200G>T p.K400N | Missense Mutation (SNP) | VAF 504/1197 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- SMARCE1 | c.310T>C p.W104R | Missense Mutation (SNP) | VAF 1846/2192 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC1A | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 359/411 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYVN1 | c.1409-5_1409-4dup | Splice Region (INS) | VAF 242/756 reads (32%) | called by mutect2, varscan2
- USP15 | c.2223del p.R742Gfs*2 (on ENST00000280377 / NM_001351159.2; = p.R713Gfs*2 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 188/1080 reads (17%) | called by mutect2, varscan2
- VSX1 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 45/404 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- WDR33 | c.2760+2T>C p.X920_splice | Splice Site (SNP) | VAF 191/463 reads (41%) | called by muse, mutect2, varscan2
- ZNF106 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 305/704 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF497 | c.469A>G p.S157G | Missense Mutation (SNP) | VAF 408/728 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- AC009779.3 | c.195T>C p.A65= | Silent (SNP) | VAF 506/901 reads (56%) | called by muse, mutect2, varscan2
- CRAMP1 | c.2844G>A p.T948= | Silent (SNP) | VAF 143/377 reads (38%) | catalogued as rs753839016; called by muse, mutect2, varscan2
- FAT4 | c.11925C>T p.C3975= | Silent (SNP) | VAF 321/913 reads (35%) | catalogued as rs764710852, COSV104405867, COSV58677612; called by muse, mutect2, varscan2
- INPP5D | c.1302G>A p.T434= (on ENST00000445964 / NM_001017915.3; = p.T433= on NM_005541.5) | Silent (SNP) | VAF 248/757 reads (33%) | catalogued as rs374758284; called by muse, mutect2, varscan2
- NMBR | c.435C>A p.I145= | Silent (SNP) | VAF 207/2536 reads (8%) | catalogued as COSV99237284; called by muse, mutect2
- PCDH12 | c.699C>T p.N233= | Silent (SNP) | VAF 190/598 reads (32%) | catalogued as rs1378138682; called by muse, mutect2, varscan2
- RNASE9 | c.456G>A p.A152= | Silent (SNP) | VAF 340/1854 reads (18%) | catalogued as rs560127702, COSV58880227; called by muse, mutect2
- SSTR3 | c.768G>A p.T256= | Silent (SNP) | VAF 199/494 reads (40%) | catalogued as rs775912597, COSV60728655; called by muse, mutect2, varscan2
- STAB2 | c.6753C>T p.T2251= | Silent (SNP) | VAF 675/1108 reads (61%) | catalogued as rs770270471, COSV101185731; called by muse, mutect2, varscan2
- XYLT2 | c.897C>T p.G299= | Silent (SNP) | VAF 68/308 reads (22%) | catalogued as rs773672770; called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 21/351 reads (6%) | called by muse, mutect2
- NRG1 | c.502+30931G>A | Intron (SNP) | VAF 356/1344 reads (26%) | catalogued as rs750558927, COSV99827170, COSV99829337; called by muse, mutect2, varscan2
- SPATA8 | n.867C>T | RNA (SNP) | VAF 416/1045 reads (40%) | catalogued as rs150122584, COSV60705548; called by muse, mutect2, varscan2
- TINAG | c.*68C>A | 3'UTR (SNP) | VAF 172/585 reads (29%) | called by muse, mutect2, varscan2
- ZNF589 | c.-24C>T | 5'UTR (SNP) | VAF 116/284 reads (41%) | catalogued as rs768856228; called by muse, mutect2, varscan2
